Gene-level copy-number profile of tumor specimen C3N-04312-02 from CPTAC case C3N-04312, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.8 years (18,938 days).
Specimen C3N-04312-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4d878d78-d458-4152-b8c1-7c1240bcfe92.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04312-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/910f4316-7d32-4b24-96d2-1ec4346da961

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 14; copy number 2: 2,983; copy number 3: 15; copy number 4: 45,757; copy number 5: 187; copy number 6: 9,379; copy number 7: 2; copy number 9: 3; copy number 10: 15; copy number 42: 2; copy number 117: 1; copy number 121: 4; copy number 124: 2; copy number 125: 5; copy number 145: 2; copy number 159: 4; copy number 193: 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,214,672, 10 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:87,659,613–88,584,530, 12 genes (within-gene range 0–2): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 39 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,249,572, 1 gene, copy number 10: TRGC2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 10: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:46,673,785–46,759,851, 1 gene, copy number 117: AC011294.1.
- chr7:50,839,363–51,022,990, 4 genes, copy number 121: AC004920.1, AC009296.1, AC004830.2, AC004830.1.
- chr7:51,471,717–51,729,716, 4 genes, copy number 159: AC005999.2, ROBO2P1, AC005999.1, RN7SL292P.
- chr7:53,366,058–53,490,439, 2 genes, copy number 124: RNU1-14P, RN7SKP218.
- chr7:53,862,233–53,947,804, 2 genes, copy number 145: HAUS6P3, LINC02854.
- chr7:54,621,025–54,656,734, 2 genes, copy number 42: RNU6-1125P, RPL31P35.
- chr7:54,933,699–55,260,256, 6 genes, copy number 125–193: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr19:43,192,702–43,269,530, 3 genes, copy number 9: PSG4, CEACAMP10, PSG9.

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
